Somatic mutation profile of tumor specimen BA2935D (aliquot aq-BA2935D) from BEATAML1.0 case 2130, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.5 years (28,672 days).
Specimen BA2935D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ff4f188-cda4-4a3f-8b63-da2b6812103a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2553D (Solid Tissue Normal), aliquot aq-BA2553D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45a6384c-2c54-4b89-9c40-8634008f194f

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFT88 | c.81C>T p.S27= (on ENST00000319980 / NM_001318493.2; = p.S18= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs560202607, COSV60676530; called by muse, mutect2, varscan2
- TTYH3 | c.1500+1006C>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
